Somatic mutation profile of tumor specimen TCGA-VR-A8EQ-01A (aliquot TCGA-VR-A8EQ-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.7 years (26,912 days).
Specimen TCGA-VR-A8EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54bbc154-2f01-4b6c-9b6e-086290c3638d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EQ-10A (Blood Derived Normal), aliquot TCGA-VR-A8EQ-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27aca90c-1a00-4316-bbca-7bf92ab90e46

The open-access MAF lists 170 somatic variants for this specimen: 126 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 40, Nonsense Mutation 8, Intron 3, Frame Shift Ins 2, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 8/12 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906850, CM110722, COSV59286247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684710; called by muse, mutect2, varscan2
- AGXT | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs759836341; called by muse, mutect2, varscan2
- BGN | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368783683, COSV59036896; called by muse, mutect2, varscan2
- CCDC178 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760077046, COSV55767541; called by muse, mutect2, varscan2
- CEP97 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs749832127; called by mutect2, varscan2
- CLSTN2 | c.1988A>C p.K663T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV101516030, COSV71722100; called by muse, mutect2, varscan2
- CNTN3 | c.1814A>C p.K605T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV99726483; called by muse, mutect2, varscan2
- CNTN4 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs374090181; called by muse, mutect2, varscan2
- CNTNAP2 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749575477; called by muse, mutect2, varscan2
- CNTNAP4 | c.2835A>T p.E945D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56666630; called by muse, mutect2, varscan2
- CSMD1 | c.5728A>C p.T1910P (on ENST00000520002; = p.T1909P on NM_033225.6) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59303381; called by muse, mutect2, varscan2
- CSMD3 | c.768T>G p.S256R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV52295814; called by muse, mutect2, varscan2
- DCC | c.1578A>C p.Q526H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV59130966; called by muse, mutect2, varscan2
- DCX | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as CM078511, COSV57570872; called by muse, mutect2, varscan2
- DHX40 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1445655506; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DYNC2H1 | c.11895dup p.P3966Sfs*20 | Frame Shift Ins (INS) | VAF 11/50 reads (22%) | catalogued as rs1310779676; called by mutect2, pindel, varscan2
- EHD3 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59029883, COSV59031752; called by muse, mutect2, varscan2
- ERICH3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs749214410, COSV104399633; called by muse, mutect2, varscan2
- FCHO1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV53181267; called by muse, mutect2, varscan2
- FGF3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782147248, COSV61925745; called by muse, mutect2, varscan2
- FSIP2 | c.18748G>A p.E6250K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV100556126; called by muse, mutect2, varscan2
- GPAT4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs746510734, COSV67840573; called by muse, mutect2, varscan2
- GREB1 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs761928277, COSV52190137; called by muse, mutect2, varscan2
- GRM3 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64469428; called by muse, mutect2, varscan2
- GSE1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs368638789; called by mutect2, varscan2
- GTF3C3 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs774688614; called by muse, mutect2, varscan2
- KLF8 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100808115; called by muse, mutect2, varscan2
- KLHL13 | c.1633T>G p.F545V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.18); catalogued as COSV53254540; called by muse, mutect2, varscan2
- KRT6C | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs533243700; called by muse, mutect2, varscan2
- LCE2B | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV64227423; called by muse, mutect2, varscan2
- LRP1B | c.10137G>T p.E3379D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.04); catalogued as COSV67192449; called by mutect2, varscan2
- LRRTM4 | c.1086A>C p.E362D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV69139890; called by muse, mutect2, varscan2
- MAP2 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758141796, COSV52301445; called by muse, mutect2, varscan2
- MMP16 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760308984, COSV54151216; called by muse, mutect2, varscan2
- MXRA5 | c.4885G>A p.A1629T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs746141262; called by mutect2, varscan2
- NEFH | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs770564187; called by muse, mutect2, varscan2
- OR1L4 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.054); catalogued as COSV99414031; called by muse, mutect2, varscan2
- OR4C16 | c.581A>C p.N194T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100113834; called by muse, mutect2, varscan2
- OR4K2 | c.94T>G p.S32A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV53849250; called by muse, mutect2, varscan2
- OR5J2 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV100399273; called by muse, mutect2, varscan2
- OR8H3 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57908874; called by muse, mutect2, varscan2
- PEG3 | c.4215A>C p.E1405D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs776446931, COSV55629146; called by muse, mutect2, varscan2
- PGM5 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs142216683, COSV67168567; called by muse, mutect2, varscan2
- PHYKPL | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs201748394; called by muse, mutect2, varscan2
- PLCL1 | c.369A>C p.K123N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756290088; called by muse, mutect2, varscan2
- PNPLA7 | c.3785C>T p.T1262M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs145220396, COSV53001327; called by muse, mutect2, varscan2
- PPFIA2 | c.3697A>G p.R1233G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as rs771142270, COSV61030232; called by mutect2, varscan2
- PRODH2 | c.1013C>T p.P338L (on ENST00000301175; = p.P262L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs182628111, COSV56560937, COSV99995404; called by muse, mutect2
- RTL4 | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV61205698; called by muse, mutect2, varscan2
- SENP6 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs756724519; called by muse, mutect2, varscan2
- SLC26A8 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV62886460; called by muse, mutect2, varscan2
- SLCO3A1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV59233571; called by muse, mutect2, varscan2
- SMG6 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs774498651, COSV53965781; called by muse, mutect2, varscan2
- STXBP3 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.545); catalogued as COSV64181534; called by muse, mutect2, varscan2
- TBCEL | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1323250113; called by muse, mutect2, varscan2
- TCEAL2 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778197135; called by muse, varscan2
- TLR4 | c.805T>G p.L269V (on ENST00000355622 / NM_138554.5; = p.L229V on NM_003266.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62923479; called by muse, mutect2, varscan2
- TMEM184B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1214474605; called by mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TPO | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV61094498; called by muse, mutect2, varscan2
- TRIM11 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs866184649, COSV52858497; called by muse, mutect2, varscan2
- TTN | c.36410T>G p.L12137R (on ENST00000591111; = p.L4713R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen possibly damaging (0.804); catalogued as COSV100598532; called by muse, mutect2, varscan2
- VPS13B | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); catalogued as rs886062535, COSV62024201; ClinVar: uncertain significance; called by muse, mutect2
- ZNF521 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV100831300, COSV64123106; called by muse, mutect2, varscan2
- ZNF620 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs199758819; called by muse, mutect2, varscan2
- ADHFE1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- AL592490.1 | c.2222T>C p.L741P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ALDH9A1 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ANGPT1 | c.679A>C p.T227P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ANGPT1 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- ARG2 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- BCHE | c.218dup p.P74Afs*9 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- BLVRA | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CCL16 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.198); called by muse, mutect2
- CCR2 | c.1068A>T p.K356N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CSMD1 | c.3203T>C p.L1068P (on ENST00000520002; = p.L1067P on NM_033225.6) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYTH3 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DAB2 | c.448A>C p.K150Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAXX | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DGKB | c.1620A>T p.E540D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by mutect2, varscan2
- EPHA10 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); called by muse, mutect2
- EYA4 | c.22A>C p.N8H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FASTKD1 | c.1701G>A p.K567= | Splice Region (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- FREM1 | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GK5 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- GRIA2 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNA4 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KIR2DS4 | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- LRRC40 | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2A2 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MARVELD3 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- MEPE | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NAV1 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- NCK2 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NLGN1 | c.1635T>G p.N545K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP14 | c.38T>G p.F13C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NRG1 | c.962A>G p.E321G (on ENST00000405005 / NM_013964.5; = p.E326G on NM_013956.5) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ODF1 | c.585T>G p.C195W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR1A1 | c.802A>C p.K268Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.542); called by muse, mutect2
- OR1L6 | c.383T>G p.V128G (on ENST00000373684; = p.V92G on NM_001004453.2) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR4C46 | c.191T>A p.L64H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5T3 | c.772A>C p.T258P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PAK6 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PDE10A | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PDX1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD2 | c.2561C>A p.A854E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PER2 | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POM121L12 | c.469A>T p.R157* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- RIMKLB | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RRBP1 | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX14 | c.1951G>A p.E651K (on ENST00000314673 / NM_001350535.1; = p.E598K on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SUPT3H | c.625T>C p.S209P (on ENST00000371460 / NM_181356.3; = p.S198P on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- TMEM132B | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- TNR | c.3316A>C p.T1106P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRIM50 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TTN | c.13387A>G p.S4463G (on ENST00000591111; = p.S4417G on NM_003319.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- UNC13C | c.5099A>C p.N1700T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VAC14 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- WSB1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YARS1 | c.119G>C p.W40S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF248 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZNF354C | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZNF521 | c.3881A>C p.K1294T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF98 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AGBL1 | c.2250C>A p.V750= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- AGL | c.4413G>A p.P1471= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1049817296, COSV54050675; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP32 | c.4926G>A p.E1642= (on ENST00000310343 / NM_001378025.1; = p.E1293= on NM_014715.4) | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- B4GALT6 | c.96C>T p.I32= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- C12orf43 | c.684G>A p.G228= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CALHM5 | c.390C>T p.S130= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs772381374, COSV62068994; called by muse, mutect2, varscan2
- CAMK4 | c.399G>A p.K133= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- CD207 | c.312A>C p.A104= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- COL1A2 | c.981C>T p.R327= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs141762645; ClinVar: benign / likely benign; called by muse, mutect2
- COL22A1 | c.3456T>C p.A1152= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- CUX2 | c.507G>A p.G169= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- CUX2 | c.1720C>A p.R574= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55635400; called by muse, mutect2, varscan2
- DENND11 | c.939G>A p.V313= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- DLGAP3 | c.978G>A p.S326= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1288105545, COSV52394482; called by muse, mutect2, varscan2
- ENDOV | c.669G>A p.L223= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- ETV6 | c.603C>T p.L201= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV67149477; called by muse, mutect2, varscan2
- FMN2 | c.462C>T p.V154= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs764454579, COSV60425774; called by muse, mutect2, varscan2
- FSCB | c.1389A>G p.K463= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- GEMIN4 | c.297G>A p.S99= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs370552236; called by muse, mutect2, varscan2
- HIVEP3 | c.4213A>C p.R1405= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- ITGA3 | c.858G>A p.Q286= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV50335233; called by muse, mutect2, varscan2
- KDM5A | c.3234C>T p.T1078= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1392115365; called by muse, mutect2, varscan2
- L1CAM | c.1476C>T p.T492= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs150805225; called by muse, varscan2
- LRP1B | c.3651T>C p.Y1217= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- MAB21L1 | c.117C>T p.S39= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1377363697, COSV59766487; called by muse, mutect2, varscan2
- MAGEC3 | c.1002A>G p.G334= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- MAGEH1 | c.660A>G p.*220= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100746781, COSV61678793; called by muse, mutect2, varscan2
- MXRA5 | c.1341G>A p.T447= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs759245624; called by muse, mutect2, varscan2
- MYH2 | c.3015C>G p.L1005= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- NOTCH1 | c.6645G>A p.S2215= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs745339419, COSV53102237; called by muse, mutect2, varscan2
- NOTCH1 | c.1365G>A p.E455= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- NPFF | c.84G>A p.Q28= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- RASGRF1 | c.2874C>T p.L958= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- RYR2 | c.618T>C p.A206= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SARDH | c.2274C>T p.H758= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs371772872, COSV64098893; called by muse, mutect2, varscan2
- TRMT11 | c.312G>A p.S104= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs756285582, COSV57672096; called by muse, mutect2, varscan2
- TRPA1 | c.78G>A p.P26= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs746121998, COSV100082921; called by muse, varscan2
- TTLL7 | c.2358C>T p.F786= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- VAT1L | c.321T>C p.S107= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100214102; called by muse, mutect2, varscan2
- ZIC3 | c.1281T>G p.S427= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- CNTN1 | c.1805-9451A>C | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- FAM74A3 | n.132_143del | RNA (DEL) | VAF 45/372 reads (12%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85686A>C | Intron (SNP) | VAF 20/64 reads (31%) | catalogued as COSV72278402; called by muse, mutect2, varscan2
- OBSCN | c.18662-2053T>G | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
